Gene-level copy-number profile of tumor specimen TCGA-85-8353-01A from TCGA case TCGA-85-8353, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.7 years (26,549 days).
Specimen TCGA-85-8353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c288b6eb-41db-4584-944d-674b50c4b945.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8353-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d4abf93-fd35-427b-aa40-ea32e40f1d93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 771; copy number 2: 24,459; copy number 3: 10,072; copy number 4: 18,217; copy number 5: 2,891; copy number 6: 2,559; copy number 8: 24; copy number 9: 591; copy number 10: 10; copy number 11: 87; copy number 15: 20; copy number 17: 5; copy number 24: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8353-01A-21D-2292-01): tumor purity 0.41, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:182,548,659–182,631,688, 2 genes: RNU2-34P, RN7SKP67.
- chr4:186,104,419–186,172,667, 1 gene (within-gene range 0–2): FAM149A.
- chr4:186,157,896–190,092,279, 79 genes (broad region; genes not listed).
- chr10:32,413,499–32,882,874, 3 genes (within-gene range 0–2): AL391839.3, CCDC7, C1DP1.
- chr10:129,278,251–131,311,721, 24 genes: AL391869.1, AL359508.1, MGMT, AL355531.1, AL157832.2, AL157832.1, LINC02666, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA, AC016816.1, MIR378C, TCERG1L, TCERG1L-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,169 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–213,794,587, 1,840 genes, copy number 6 (broad region; genes not listed).
- chr1:215,376,484–217,631,090, 11 genes, copy number 6 (within-gene range 4–6): VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG, GPATCH2.
- chr1:222,452,738–241,519,755, 444 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–4,140,731, 71 genes, copy number 5 (broad region; genes not listed).
- chr3:90,202,316–198,222,513, 1,804 genes, copy number 5–9 (broad region; genes not listed).
- chr6:164,346,489–170,738,536, 135 genes, copy number 6 (broad region; genes not listed).
- chr8:73,688,691–145,066,685, 1,115 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:128,181,032–128,968,740, 5 genes, copy number 24 (within-gene range 2–24): LINC01163, AL390763.1, LINC02667, AL355537.1, AL355537.2.
- chr12:68,487,687–73,208,317, 86 genes, copy number 6–10 (broad region; genes not listed).
- chr12:77,129,178–78,540,675, 11 genes, copy number 11–17 (within-gene range 2–17): AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1.
- chr18:47,390–6,415,237, 125 genes, copy number 8–15 (within-gene range 4–15) (broad region; genes not listed).
- chr18:23,598,926–24,987,919, 33 genes, copy number 5 (within-gene range 1–5): ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894.
- chr19:27,638,483–40,629,818, 489 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 771. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
